Surgical pathology report (de-identified scan), TCGA case TCGA-Z4-A8JB, project TCGA-SARC (Sarcoma), tissue source site Cureline, specimen TCGA-Z4-A8JB-01A (Primary Tumor).

Case #

Patient: Age (years): Gender: F

Clinical diagnosis: Sarcoma

Date of procurement:

Sample:

Gross description: Single block contains skin patch 6-14 cm with subcutaneous adipose tissue 2 cm thick. Skeletal muscle 13x6x3.5 cm, fragment of costal cartilage 3-4 cm. Section shows tumor mass in skeletal muscle and subcutaneous adipose tissue without clear margins, 9x5.8x3.8 cm, with fibrous structure, white, invading costal cartilages (I).

Tumor location:

0.2 cm from upper costal (IV)

0.1 cm from lower costal (V)

0.8 cm from frontal (VI)

0.1 cm from posterior (VII)

3 cm from medial (II)

2 cm from lateral (III)

ICD-O-3
Desmoid NOS 8821/1
Site ^{CSCC} Chest NOS C49.3
^{path} Abdominal wall NOS
C49.4
JW 1/27/14

Microscopic description: Sections reveal tumor mass in frontal abdominal wall with fibro-desmoid appearance, infiltrating striated musculature and costal cartilages. Surgical margins are clear. Histology consistent with desmoids sarcoma

Final diagnosis: Sarcoma of the abdominal wall, desmoid type

Confidential

HPA Discrepancy		✓
For Discrepancy History		✓
Path/Synchroscopy: Primary/Noted		✓

Source: NCI Genomic Data Commons file 71939cc4-16c4-4c5b-a4e5-d71134c1ca02 (TCGA-Z4-A8JB.C3019CCF-9E1F-4C37-94EC-9D3603D79D0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).